Gene-level copy-number profile of tumor specimen TCGA-29-1704-01B from TCGA case TCGA-29-1704, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 61.6 years (22,511 days).
Specimen TCGA-29-1704-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.eeb37d58-b09e-4a3b-a134-1f553c22127a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-29-1704-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/eb9a97f5-3812-4c4e-9056-c88efb3d8ca9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 15,493; copy number 2: 34,459; copy number 3: 7,740; copy number 4: 894; copy number 5: 1,228.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-29-1704-01): tumor purity 0.74, ploidy 1.97, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:134,706,060–134,707,349, 1 gene: AL121970.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,228 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:175,904,371–176,849,428, 35 genes, copy number 5: AC016751.1, LNPK, EVX2, HOXD13, HOXD12, HOXD11, HOXD10, HOXD-AS2, HOXD9, HOXD8, HOXD3, MIR10B, HOXD4, HAGLR, AC009336.1, HAGLROS, HOXD1, MIR7704, AC009336.2, AC016739.1, RPSAP25, MTX2, PPIAP67, LINC01117, AC017048.1, AC017048.2, MIR1246, AC017048.3, LINC01116, RNU6ATAC14P, AC092162.2, FUCA1P1, AC092162.1, AC092162.3, AC073636.1.
- chr2:190,189,735–190,882,059, 11 genes, copy number 5: HIBCH, INPP1, MFSD6, AC093388.1, NEMP2, AC108047.1, RN7SKP179, AC006460.2, NAB1, AC006460.1, AC005540.1.
- chr3:124,080,023–124,726,325, 1 gene, copy number 5 (within-gene range 3–5): KALRN.
- chr3:124,151,960–124,953,819, 13 genes, copy number 5: RPL7P15, MIR6083, RNU6-143P, AC022336.2, UMPS, MIR544B, AC022336.1, ITGB5, ITGB5-AS1, AC022336.3, 7SK, ENO1P3, MUC13.
- chr3:133,824,235–198,222,513, 1,111 genes, copy number 5 (broad region; genes not listed).
- chr7:27,412,164–28,180,795, 10 genes, copy number 5 (within-gene range 3–5): AC004009.2, EIF4HP1, PSMC1P2, AC073150.1, HIBADH, AC007130.1, TAX1BP1-AS1, TAX1BP1, JAZF1, AC004549.1.
- chr9:129,036,621–129,753,042, 29 genes, copy number 5: MIGA2, AL592211.2, DOLPP1, CRAT, AL158151.2, PTPA, AL158151.3, AL158151.4, IER5L, AL158151.1, AL161785.1, C9orf106, AL353803.5, LINC01503, RN7SL159P, AL353803.3, AL353803.2, AL353803.1, LINC00963, AL353803.4, AL391056.2, AL391056.1, NTMT1, C9orf50, ASB6, AL590369.1, PRRX2, PRRX2-AS1, PTGES.
- chr13:113,491,021–113,554,590, 1 gene, copy number 5 (within-gene range 3–5): TMCO3.
- chr13:113,527,260–114,132,623, 17 genes, copy number 5: AL442125.1, TFDP1, ATP4B, GRK1, LINC00552, TMEM255B, GAS6-AS1, GAS6, GAS6-DT, BX072579.1, LINC00454, BX072579.2, LINC00452, LINC00565, C13orf46, RASA3, RASA3-IT1.

Autosomal genes at a single copy (total copy number 1): 15,493. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
